Gene-level copy-number profile of tumor specimen TCGA-DD-AACD-01A from TCGA case TCGA-DD-AACD, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G4; Age at diagnosis: 48.8 years (17,828 days).
Specimen TCGA-DD-AACD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.be01053f-0e51-4e12-900a-09107fc0a5e0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AACD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6f7b02a5-0970-4d3f-8697-06aaa16cde5c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 3,767; copy number 2: 47,724; copy number 3: 6,588; copy number 4: 345; copy number 7: 1,368.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AACD-01A-11D-A40Q-01): tumor purity 0.7, ploidy 2.23, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:205,253,304–205,253,503, 1 gene: AC008171.1.
- chr6:169,419,969–169,702,047, 1 gene (within-gene range 0–1): AL031315.1.
- chr6:169,457,212–169,781,600, 8 genes (within-gene range 0–1): WDR27, C6orf120, PHF10, AL354892.2, AL354892.1, TCTE3, ERMARD, AL354892.3.
- chr8:18,774,547–18,774,918, 1 gene: RPL35P6.
- chr9:109,375,466–109,498,313, 1 gene (within-gene range 0–2): PTPN3.
- chr9:109,511,475–109,534,332, 2 genes: MIR3927, YBX1P6.
- chr18:79,069,285–79,378,287, 1 gene (within-gene range 0–1): ATP9B.
- chr18:79,144,752–79,354,567, 5 genes: AC125437.2, AC125437.3, AC104423.1, AC023090.1, AC023090.2.
- chr22:27,978,014–28,679,865, 1 gene (within-gene range 0–2): TTC28.
- chr22:28,459,869–28,742,422, 3 genes: MIR5739, RN7SL162P, CHEK2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,368 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:56,300,010–128,187,101, 1,047 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:128,049,152–145,066,685, 321 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,767. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
